Somatic mutation profile of tumor specimen TCGA-DV-5576-01A (aliquot TCGA-DV-5576-01A-01D-1534-10) from TCGA case TCGA-DV-5576, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.6 years (20,310 days).
Specimen TCGA-DV-5576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 386e8bac-8c4c-417d-9655-109d59787a29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5576-10A (Blood Derived Normal), aliquot TCGA-DV-5576-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb124da7-de5d-4828-a9f4-5a88a99863b0

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.1489A>G p.M497V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs746127117, COSV51973713; called by muse, mutect2, varscan2
- AGK | c.724A>T p.K242* | Nonsense Mutation (SNP) | VAF 313/981 reads (32%) | catalogued as COSV62595510; called by muse, mutect2, varscan2
- ATRX | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64881004; called by muse, mutect2, varscan2
- ICMT | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs945195580, COSV59474271; called by muse, mutect2, varscan2
- KRTAP4-1 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs764999546, COSV66649530; called by muse, mutect2, varscan2
- NTRK1 | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62327683; called by muse, mutect2, varscan2
- SAMD9L | c.4231C>G p.R1411G | Missense Mutation (SNP) | VAF 108/395 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); catalogued as COSV59083498, COSV59084096; called by muse, mutect2, varscan2
- SLC3A2 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58604406; called by muse, mutect2, varscan2
- TOP2A | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs192926120; called by muse, mutect2, varscan2
- TTN | c.82693G>A p.E27565K (on ENST00000591111; = p.E20141K on NM_003319.4) | Missense Mutation (SNP) | VAF 110/320 reads (34%) | PolyPhen benign (0.167); catalogued as rs1364550008, COSV60243937; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHJ6 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 60/206 reads (29%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHV3-43 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MRC1 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 204/587 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1E | c.3333G>A p.V1111= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as rs569675496, COSV62410237; called by muse, mutect2, varscan2
- STK35 | c.1533T>A p.A511= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV55691597, COSV55692276; called by muse, mutect2, varscan2
